Somatic mutation profile of tumor specimen ALCH-B1XS-TTP1-A (aliquot ALCH-B1XS-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1XS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.8 years (21,842 days).
Specimen ALCH-B1XS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 206ef3de-9c38-45e5-bb7a-95fbbada4b4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1XS-NB1-A (Blood Derived Normal), aliquot ALCH-B1XS-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bdf879d-720d-479a-992f-760ebbc1c9e0

The open-access MAF lists 117 somatic variants for this specimen: 83 protein-altering or splice-affecting, 25 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 25, Nonsense Mutation 4, Splice Site 4, RNA 3, Frame Shift Del 3, Intron 2, 5'UTR 2, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 47/290 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 16/104 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CDH18 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 28/344 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV56923804, COSV99939160; called by muse, mutect2
- CEBPG | c.324C>G p.I108M | Missense Mutation (SNP) | VAF 56/349 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1313833097; called by muse, varscan2
- CTNND2 | c.2695G>T p.E899* | Nonsense Mutation (SNP) | VAF 21/201 reads (10%) | catalogued as COSV58879539; called by muse, mutect2, varscan2
- DPT | c.210C>A p.D70E | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs373094371; called by muse, mutect2
- FUNDC2 | c.86G>T p.R29L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.091); catalogued as COSV100811297; called by muse, mutect2, varscan2
- HDX | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.968); catalogued as COSV52977159, COSV52982203; called by muse, mutect2, varscan2
- ISM1 | c.1014C>G p.F338L | Missense Mutation (SNP) | VAF 41/294 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs757051405, COSV52603301; called by muse, mutect2, varscan2
- KLHDC4 | c.1507G>T p.A503S | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as COSV54511112; called by mutect2, varscan2
- LRP2 | c.3166G>C p.D1056H | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55558862, COSV99787750; called by muse, mutect2
- MAGEC2 | c.902G>T p.W301L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99909834; called by muse, mutect2, varscan2
- MUC16 | c.41615G>A p.G13872E | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.991); catalogued as COSV101110019; called by muse, mutect2
- MYBBP1A | c.1066G>C p.V356L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV54598303; called by muse, varscan2
- NF1 | c.7189+1G>C p.X2397_splice (on ENST00000358273 / NM_001042492.3; = p.X2376_splice on NM_000267.3) | Splice Site (SNP) | VAF 35/159 reads (22%) | catalogued as CS1311549, COSV62213986; called by muse, mutect2, varscan2
- NLRP8 | c.1811G>T p.S604I | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV52594353; called by muse, mutect2, varscan2
- OR2M5 | c.120G>T p.M40I | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV63545820, COSV63546052; called by muse, mutect2
- PAPPA2 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100866766; called by muse, mutect2
- PAPPA2 | c.1658C>A p.A553E | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV62781547; called by muse, mutect2, varscan2
- PLSCR4 | c.742G>T p.G248W | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100724099; called by muse, mutect2
- POM121L12 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as rs777494478, COSV68694799; called by muse, mutect2
- PSMD13 | c.828C>A p.C276* | Nonsense Mutation (SNP) | VAF 14/168 reads (8%) | catalogued as COSV61501704; called by muse, mutect2
- ROBO3 | c.1802C>A p.T601K | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); catalogued as rs1565312111; called by muse, mutect2
- TMX3 | c.639G>T p.E213D | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs1175503230; called by muse, mutect2
- TRAV21 | c.46+2T>A p.X16_splice | Splice Site (SNP) | VAF 23/153 reads (15%) | catalogued as rs759793341; called by muse, mutect2, varscan2
- ZNF423 | c.2996G>T p.R999L (on ENST00000563137 / NM_001379286.1; = p.R991L on NM_015069.4) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.289); catalogued as COSV52202691; called by muse, mutect2, varscan2
- ZNF99 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV68055495; called by muse, mutect2, varscan2
- ADAMTS16 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.75); called by muse, mutect2
- AOC3 | c.1514G>T p.G505V | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.134); called by muse, mutect2
- AREL1 | c.866C>G p.S289C | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2
- ASTN2 | c.1302G>T p.K434N (on ENST00000313400 / NM_001365069.1; = p.K383N on NM_014010.5) | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2
- ATIC | c.599G>C p.G200A | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.044); called by muse, mutect2
- ATP2B1 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.202); called by muse, mutect2
- C1QTNF4 | c.349G>C p.A117P | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2
- CCM2L | c.17A>G p.K6R | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); called by muse, mutect2
- CHRM3 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 15/207 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHRNA4 | c.570C>A p.D190E | Missense Mutation (SNP) | VAF 19/276 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); called by muse, mutect2
- CMTR2 | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH6 | c.1720G>T p.G574* | Nonsense Mutation (SNP) | VAF 38/447 reads (9%) | called by muse, mutect2
- GAPDHS | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); called by muse, mutect2
- GDF2 | c.257C>A p.P86Q | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXA2 | c.316A>G p.K106E | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); called by muse, mutect2
- IGKV2D-24 | c.169T>A p.Y57N | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); called by muse, mutect2
- IGLV2-8 | c.235G>T p.V79F | Missense Mutation (SNP) | VAF 86/483 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- IMPG2 | c.3068C>T p.S1023L | Missense Mutation (SNP) | VAF 36/332 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- KCNJ1 | c.790T>G p.S264A | Missense Mutation (SNP) | VAF 30/443 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.118); called by muse, mutect2
- KCNN4 | c.487G>T p.V163L | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.057); called by muse, mutect2
- KLHL7 | c.1688C>T p.A563V (on ENST00000339077 / NM_001031710.3; = p.A515V on NM_018846.5) | Missense Mutation (SNP) | VAF 57/527 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LRRC7 | c.2660C>A p.P887H (on ENST00000651989 / NM_001370785.2; = p.P854H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRTM1 | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 13/316 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2
- MAGEE1 | c.638del p.P213Rfs*8 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel*, varscan2*
- MAGEL2 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- MUC16 | c.21104G>A p.G7035D | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NAT10 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 33/285 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCKAP5 | c.4043G>T p.G1348V | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NOTCH1 | c.7031A>G p.H2344R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.201); called by muse, mutect2
- NT5M | c.272del p.K91Rfs*71 | Frame Shift Del (DEL) | VAF 23/137 reads (17%) | called by mutect2, pindel, varscan2
- OR10R2 | c.782G>T p.C261F | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2D3 | c.111G>T p.L37F | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- PARG | c.910A>G p.M304V | Missense Mutation (SNP) | VAF 47/468 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- PDGFRA | c.320C>A p.T107K | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.92); PolyPhen benign (0.005); called by muse, mutect2
- PLCB1 | c.2720C>A p.A907E | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.901); called by muse, mutect2
- PLCXD3 | c.242C>A p.T81K | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- PRDM15 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); called by muse, mutect2
- PRKD3 | c.1517A>T p.H506L | Missense Mutation (SNP) | VAF 62/468 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PXDNL | c.500C>A p.S167Y | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.316); called by muse, mutect2
- RAB3D | c.95G>A p.S32N | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2
- RALGPS1 | c.1324A>T p.T442S | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- RASEF | c.1113+1G>T p.X371_splice | Splice Site (SNP) | VAF 28/228 reads (12%) | called by muse, mutect2, varscan2
- SLC8A1 | c.172G>C p.G58R | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLFN5 | c.2074A>T p.S692C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SNRK | c.902G>C p.R301P | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2
- SNRNP70 | c.419C>G p.S140* | Nonsense Mutation (SNP) | VAF 35/173 reads (20%) | called by muse, mutect2, varscan2
- SORCS2 | c.3142C>A p.Q1048K | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- ST8SIA6 | c.595C>A p.L199I | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.357); called by muse, mutect2
- SYNE2 | c.7110A>C p.K2370N | Missense Mutation (SNP) | VAF 21/248 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- UBP1 | c.173_183del p.E58Afs*19 | Frame Shift Del (DEL) | VAF 14/124 reads (11%) | called by mutect2, pindel
- USH1C | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- XPNPEP1 | c.1873-1G>T p.X625_splice | Splice Site (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- ZFHX4 | c.3355G>T p.D1119Y | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2
- ZFR2 | c.1818G>T p.E606D | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- ZNF136 | c.746A>G p.D249G | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); called by muse, varscan2
- ZNF559-ZNF177 | c.653T>A p.I218N | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- AKT3 | c.1107C>A p.L369= | Silent (SNP) | VAF 23/211 reads (11%) | catalogued as COSV55616604; called by muse, mutect2, varscan2
- CAPN13 | c.1365C>T p.N455= | Silent (SNP) | VAF 42/375 reads (11%) | called by muse, mutect2
- CHD1L | c.2587C>T p.L863= | Silent (SNP) | VAF 10/96 reads (10%) | called by muse, varscan2
- GALM | c.117G>T p.T39= | Silent (SNP) | VAF 9/212 reads (4%) | called by muse, mutect2
- GLI3 | c.2823G>T p.P941= | Silent (SNP) | VAF 22/201 reads (11%) | catalogued as rs1265840227; called by muse, mutect2, varscan2
- GZMA | c.306C>A p.P102= | Silent (SNP) | VAF 30/208 reads (14%) | called by muse, mutect2, varscan2
- HR | c.2064G>T p.G688= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV57193657; called by muse, mutect2, varscan2
- KCNH2 | c.1245G>C p.L415= | Silent (SNP) | VAF 12/245 reads (5%) | catalogued as rs1411817701; called by muse, mutect2
- LURAP1 | c.585G>A p.L195= | Silent (SNP) | VAF 13/240 reads (5%) | called by muse, mutect2
- MAP1LC3B2 | c.96G>A p.P32= | Silent (SNP) | VAF 26/350 reads (7%) | catalogued as rs774340612; called by muse, mutect2
- MUC16 | c.7800T>C p.T2600= | Silent (SNP) | VAF 12/167 reads (7%) | called by muse, mutect2
- MYH11 | c.2545C>A p.R849= | Silent (SNP) | VAF 45/460 reads (10%) | catalogued as rs869025471; called by muse, mutect2, varscan2
- PCARE | c.585C>A p.L195= | Silent (SNP) | VAF 23/196 reads (12%) | called by muse, mutect2, varscan2
- PCDHA5 | c.1758G>A p.A586= | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as rs1472583465; called by muse, mutect2
- PDXK | c.45C>T p.I15= | Silent (SNP) | VAF 13/93 reads (14%) | called by muse, mutect2
- RSF1 | c.1332A>C p.G444= | Silent (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- SHROOM2 | c.3630G>T p.V1210= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- SLC22A11 | c.135A>C p.P45= | Silent (SNP) | VAF 6/146 reads (4%) | called by muse, mutect2
- SLC39A5 | c.1350C>T p.L450= | Silent (SNP) | VAF 24/280 reads (9%) | catalogued as rs373073769; called by muse, mutect2
- TGFBR3 | c.2373G>T p.A791= | Silent (SNP) | VAF 26/300 reads (9%) | catalogued as COSV53022654; called by muse, mutect2
- TMEM196 | c.351C>A p.G117= | Silent (SNP) | VAF 20/232 reads (9%) | catalogued as rs982929906, COSV68255328; called by muse, mutect2
- TMEM225B | c.159A>C p.L53= | Silent (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- UNC5C | c.2055C>A p.A685= | Silent (SNP) | VAF 12/300 reads (4%) | called by muse, mutect2
- UROC1 | c.1350C>A p.R450= | Silent (SNP) | VAF 14/192 reads (7%) | called by muse, mutect2
- ZNF208 | c.3495A>T p.V1165= | Silent (SNP) | VAF 30/210 reads (14%) | called by muse, mutect2, varscan2
- CD84 | c.812-21C>A | Intron (SNP) | VAF 30/265 reads (11%) | called by muse, mutect2, varscan2
- EIF2B5 | c.321-15C>T | Intron (SNP) | VAF 16/242 reads (7%) | called by muse, mutect2
- FSHR | c.-49G>T | 5'UTR (SNP) | VAF 18/140 reads (13%) | called by muse, mutect2, varscan2
- IGKV2-29 | n.307G>C | RNA (SNP) | VAF 26/346 reads (8%) | called by muse, mutect2
- PCDHB6 | chr5:141156598 G>A | 3'Flank (SNP) | VAF 18/146 reads (12%) | called by muse, mutect2, varscan2
- PPA1 | c.-3A>T | 5'UTR (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2, varscan2
- RPL23AP42 | n.38C>G | RNA (SNP) | VAF 14/180 reads (8%) | called by muse, mutect2
- ZNF322P1 | n.277C>T | RNA (SNP) | VAF 25/398 reads (6%) | called by muse, mutect2
- ZNF99 | c.*2977T>A | 3'UTR (SNP) | VAF 28/185 reads (15%) | called by muse, varscan2
